Gene-level copy-number profile of specimen HCM-BROD-0569-C43-85M from HCMI case HCM-BROD-0569-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 78.3 years (28,586 days).
Specimen HCM-BROD-0569-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2fd0426b-f4ec-4b54-b038-98a6b3912e09.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0569-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/2bb5037a-723b-4d5f-ae19-aa1959b99e4e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 369; copy number 2: 1,839; copy number 3: 21,752; copy number 4: 27,561; copy number 5: 3,191; copy number 6: 778; copy number 7: 2,794; copy number 8: 8; copy number 9: 40; copy number 10: 57.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 97 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:549,197–727,650, 1 gene, copy number 10 (within-gene range 5–10): PRKAR1B.
- chr7:726,699–2,844,308, 56 genes, copy number 10: DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1, MAD1L1, AC069288.1, AC104129.1, MIR4655, MRM2, NUDT1, SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1, GNA12, AC006028.1.
- chr7:3,301,252–4,269,000, 1 gene, copy number 9 (within-gene range 8–9): SDK1.
- chr7:3,642,815–5,606,655, 39 genes, copy number 9: AC011284.1, AC017000.1, CYP3A54P, FOXK1, AC092428.1, AP5Z1, MIR4656, AC092610.1, RADIL, Y_RNA, PAPOLB, RPL22P16, MMD2, RNF216P1, AC092032.2, RBAK-RBAKDN, AC092032.3, AC092032.1, SPDYE19P, RBAK, RBAKDN, OR10AH1P, ZNF890P, RNU6-215P, WIPI2, SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1.

Autosomal genes at a single copy (total copy number 1): 369. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
